Somatic mutation profile of tumor specimen ALCH-B26K-TTP1-A (aliquot ALCH-B26K-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B26K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.3 years (19,836 days).
Specimen ALCH-B26K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c544a6e-f116-4de3-a703-ca42e85bea83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26K-NB1-A (Blood Derived Normal), aliquot ALCH-B26K-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58ebcf77-304f-402e-ac16-62359bb0c9bd

The open-access MAF lists 181 somatic variants for this specimen: 120 protein-altering or splice-affecting, 39 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 39, Nonsense Mutation 9, Intron 8, RNA 7, Splice Site 5, Splice Region 4, Frame Shift Del 4, 3'UTR 3, 5'UTR 3, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 97/385 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.936del p.K312Nfs*24 | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | catalogued as rs397518443; ClinVar: pathogenic; called by mutect2, varscan2
- AGXT2 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs1423688970, COSV51488199; called by muse, mutect2
- ALG13 | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs779841344; called by muse, mutect2, varscan2
- ALS2CL | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs375865019; called by muse, mutect2, varscan2
- ASB2 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.104); catalogued as COSV60113602; called by muse, mutect2, varscan2
- ATP5MC3 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99507234; called by muse, mutect2, varscan2
- B3GAT2 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57775591; called by muse, mutect2, varscan2
- BTBD8 | c.4277G>A p.R1426H (on ENST00000636805 / NM_001376131.1; = p.R913H on NM_015237.4) | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs903908547; called by muse, mutect2, varscan2
- CACNA1C | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs755579963, COSV100217680, COSV59753819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV70471466; called by muse, mutect2, varscan2
- COL11A1 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617821; called by muse, mutect2, varscan2
- COL3A1 | c.1249G>T p.G417* | Nonsense Mutation (SNP) | VAF 113/385 reads (29%) | catalogued as CM001092; called by muse, mutect2, varscan2
- DOCK11 | c.1730C>A p.T577N | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV52246841; called by muse, mutect2, varscan2
- ESR2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.835); catalogued as rs767100418; called by muse, mutect2, varscan2
- GATA4 | c.1044C>A p.S348R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1424549925; called by muse, mutect2, varscan2
- GDNF | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1463572975; called by muse, mutect2, varscan2
- GLT1D1 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 30/174 reads (17%) | catalogued as rs1348107210; called by muse, mutect2, varscan2
- HADHA | c.1885+1G>T p.X629_splice | Splice Site (SNP) | VAF 34/179 reads (19%) | catalogued as rs1285852180; called by muse, mutect2, varscan2
- INPPL1 | c.3394G>T p.E1132* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV53358507; called by muse, varscan2
- ITGB3BP | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs761729867; called by muse, mutect2, varscan2
- KIF3C | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs1194053115; called by muse, mutect2, varscan2
- LUZP2 | c.525G>A p.A175= | Splice Region (SNP) | VAF 48/207 reads (23%) | catalogued as rs148359334; called by muse, mutect2, varscan2
- NRK | c.2285C>A p.S762* | Nonsense Mutation (SNP) | VAF 48/202 reads (24%) | catalogued as COSV54607441; called by muse, mutect2, varscan2
- OR5H2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.158); catalogued as rs1438756389; called by muse, mutect2, varscan2
- OR6V1 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV69236908, COSV69237197; called by muse, varscan2
- PCDH17 | c.1334G>C p.R445P | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64977771; called by muse, mutect2, varscan2
- PEX1 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs750276597; called by muse, mutect2, varscan2
- PGBD1 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 148/353 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs765898962; called by muse, mutect2, varscan2
- PGGHG | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1338825989; called by muse, mutect2, varscan2
- POLA1 | c.2548G>T p.G850C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100985729; called by muse, mutect2, varscan2
- PRICKLE2 | c.2476G>C p.A826P (on ENST00000295902; = p.A770P on NM_198859.4) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.67); catalogued as COSV55765507; called by muse, mutect2, varscan2
- SLC26A1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs751905449; called by muse, mutect2, varscan2
- SPRY3 | c.465C>A p.C155* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV57142857; called by muse, mutect2, varscan2
- TRIM51 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs757831621; called by muse, mutect2, varscan2
- UFL1 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV100990159; called by muse, mutect2, varscan2
- ZIC4 | c.-15-1G>T | Splice Site (SNP) | VAF 54/173 reads (31%) | catalogued as COSV101267912; called by muse, mutect2, varscan2
- ACSS1 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- AHNAK2 | c.5188C>A p.P1730T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ANKRD30A | c.2971C>A p.Q991K (on ENST00000611781; = p.Q935K on NM_052997.2) | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARPP21 | c.1385C>A p.T462N | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- ATF6B | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BEND2 | c.2000G>T p.W667L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.047); called by muse, mutect2
- BEND2 | c.1999T>A p.W667R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- C6 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.5619G>T p.K1873N | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CTNND1 | c.2639-4A>G | Splice Region (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- CUBN | c.8853G>T p.E2951D | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCDC1 | c.1348A>T p.I450F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DENND5B | c.2183T>A p.I728N | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DMD | c.5195A>G p.D1732G | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DPPA4 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2
- DRC1 | c.882T>A p.D294E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ELFN2 | c.1997A>T p.K666M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FAM98B | c.90A>T p.L30F | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FGD2 | c.1459-1G>T p.X487_splice | Splice Site (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- GDPD4 | c.1638C>A p.H546Q | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); called by muse, mutect2
- GDPD4 | c.1636C>A p.H546N | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.088); called by muse, mutect2
- GRIA3 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- HADHA | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELQ | c.2414A>T p.Y805F | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HMX3 | c.806C>A p.T269K | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS6L | c.114G>T p.L38= | Splice Region (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- IRF2BPL | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ITGAD | c.2270T>C p.L757P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ITGAX | c.2065del p.R689Vfs*12 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by pindel, varscan2
- KEAP1 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLRC4 | c.77del p.G26Afs*16 | Frame Shift Del (DEL) | VAF 63/258 reads (24%) | called by mutect2, pindel, varscan2
- KY | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- LONRF3 | c.1933G>A p.G645S (on ENST00000371628 / NM_001031855.3; = p.G604S on NM_024778.5) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC37A | c.3002C>A p.P1001Q | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.218); called by mutect2, varscan2
- MAEA | c.1133G>A p.C378Y (on ENST00000303400 / NM_001017405.3; = p.C337Y on NM_005882.5) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEA8 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC16 | c.35923G>T p.A11975S | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2
- MUC19 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC5AC | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); called by muse, mutect2, varscan2
- NALCN | c.108A>T p.P36= | Splice Region (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- NF1 | c.4682G>T p.S1561I (on ENST00000358273 / NM_001042492.3; = p.S1540I on NM_000267.3) | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NOS3 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLIG2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- OR4Q2 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR52B6 | c.709T>A p.Y237N | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5D13 | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OR5H1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.081); called by muse, varscan2
- PPP4R3C | c.1531C>A p.L511I | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRELID3A | c.156G>T p.L52F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PRTG | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PTGS1 | c.675T>A p.H225Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2
- PTPRB | c.5219A>T p.D1740V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB4A | c.541+1G>T p.X181_splice | Splice Site (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- RABGGTB | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RPGR | c.200T>A p.L67* | Nonsense Mutation (SNP) | VAF 67/458 reads (15%) | called by muse, mutect2, varscan2
- RPP25L | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RYR2 | c.8355G>A p.W2785* | Nonsense Mutation (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- SCN10A | c.4584C>A p.F1528L | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SCN5A | c.2270C>A p.T757K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SIGLEC6 | c.534del p.I179Sfs*39 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- SLC10A3 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC13A2 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC3A1 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 115/420 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SLCO2A1 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SUGP1 | c.231dup p.C78Lfs*11 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- TAOK1 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX18 | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THBS3 | c.1485T>G p.D495E | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM130 | c.922C>G p.P308A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- TRO | c.2152A>T p.S718C | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TRPA1 | c.3354G>T p.E1118D | Missense Mutation (SNP) | VAF 135/746 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TSPOAP1 | c.3826G>T p.G1276C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TTC34 | c.3142G>T p.V1048L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- UGT3A1 | c.1159G>T p.G387* | Nonsense Mutation (SNP) | VAF 62/280 reads (22%) | called by muse, mutect2, varscan2
- VCAN | c.7619C>A p.T2540N | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- VEGFD | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- XIRP2 | c.9412G>A p.E3138K (on ENST00000628543; = p.E3313K on NM_152381.6) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZFP90 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZMYM2 | c.3787C>T p.Q1263* | Nonsense Mutation (SNP) | VAF 59/175 reads (34%) | called by muse, mutect2, varscan2
- ZNF202 | c.1699T>C p.C567R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF267 | c.2000A>C p.K667T | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ADGRA3 | c.3024A>T p.A1008= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV51563930; called by muse, mutect2, varscan2
- AGXT2 | c.570C>T p.I190= | Silent (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2
- ALDH1A1 | c.1395C>T p.P465= | Silent (SNP) | VAF 59/271 reads (22%) | catalogued as COSV52793164; called by muse, mutect2, varscan2
- ARHGEF28 | c.2226G>T p.P742= | Silent (SNP) | VAF 58/204 reads (28%) | catalogued as rs758119684; called by muse, mutect2, varscan2
- ATP13A1 | c.1158G>T p.G386= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- CENPB | c.1191C>T p.I397= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CERKL | c.1221G>A p.Q407= (on ENST00000339098 / NM_001030311.2; = p.Q381= on NM_201548.5) | Silent (SNP) | VAF 171/564 reads (30%) | called by muse, mutect2, varscan2
- CFP | c.567C>A p.V189= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV55950910; called by muse, mutect2, varscan2
- D2HGDH | c.960G>T p.L320= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs1485171306; called by muse, mutect2, varscan2
- EFCAB13 | c.2334A>T p.I778= | Silent (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- ESR2 | c.852C>A p.R284= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- FSTL5 | c.2454C>A p.L818= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- FTSJ1 | c.130C>A p.R44= | Silent (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- GRIK2 | c.2604C>T p.S868= | Silent (SNP) | VAF 53/161 reads (33%) | called by muse, mutect2, varscan2
- HMCN2 | c.5148C>T p.P1716= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1461736975; called by muse, mutect2, varscan2
- IGSF9B | c.888G>A p.E296= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- IQSEC1 | c.1692G>T p.L564= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- KLF6 | c.462G>T p.L154= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV51493889; called by muse, varscan2
- L1CAM | c.267G>T p.S89= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs782641422, COSV100649302; called by muse, mutect2, varscan2
- MYO1A | c.171T>C p.Y57= | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as rs952390713; called by muse, mutect2, varscan2
- NBEA | c.2176C>T p.L726= | Silent (SNP) | VAF 60/256 reads (23%) | called by muse, mutect2, varscan2
- NOBOX | c.1659G>T p.P553= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56196512; called by muse, mutect2, varscan2
- NRK | c.1770C>A p.P590= | Silent (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- NUTM1 | c.876G>A p.E292= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- OR5D13 | c.666T>A p.L222= | Silent (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.2103C>G p.S701= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2
- PLXNB3 | c.2691T>A p.P897= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- SLC7A3 | c.867G>C p.V289= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV53226573; called by muse, mutect2
- SORL1 | c.2337C>G p.T779= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, mutect2, varscan2
- TADA2B | c.915G>T p.S305= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- TEKT2 | c.1071G>A p.A357= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs547869588, COSV99255359; called by mutect2, varscan2
- TENM2 | c.199C>A p.R67= | Silent (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2058T>C p.N686= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs752701260; called by muse, mutect2, varscan2
- TSPYL6 | c.1008C>A p.P336= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- UBR4 | c.4551C>T p.T1517= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1158G>A p.V386= | Silent (SNP) | VAF 61/282 reads (22%) | called by muse, mutect2, varscan2
- USH2A | c.8292T>A p.P2764= | Silent (SNP) | VAF 38/161 reads (24%) | called by muse, mutect2, varscan2
- USP29 | c.2631G>T p.G877= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as rs1202302930; called by muse, mutect2, varscan2
- VWA5B2 | c.2001C>A p.L667= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- AC005324.2 | c.-38G>C | 5'UTR (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2
- AC005400.1 | n.179-2799G>T | Intron (SNP) | VAF 47/240 reads (20%) | called by muse, mutect2, varscan2
- AC005400.1 | n.179-2798G>T | Intron (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- ACSL1 | c.310+120C>G | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- DCLRE1CP1 | n.244G>A | RNA (SNP) | VAF 69/254 reads (27%) | catalogued as rs547881866; called by muse, mutect2, varscan2
- FTH1 | c.115-38G>A | Intron (SNP) | VAF 112/447 reads (25%) | called by muse, mutect2, varscan2
- GRIN3A | c.-51G>T | 5'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.1193del | RNA (DEL) | VAF 38/153 reads (25%) | called by mutect2, pindel, varscan2
- LRRC37A5P | n.310G>T | RNA (SNP) | VAF 41/164 reads (25%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85458G>T | Intron (SNP) | VAF 55/277 reads (20%) | catalogued as COSV72284721; called by muse, varscan2
- MGAT4FP | n.658C>A | RNA (SNP) | VAF 24/100 reads (24%) | called by mutect2, varscan2
- MGAT4FP | n.657C>A | RNA (SNP) | VAF 27/103 reads (26%) | catalogued as rs958557884; called by muse, mutect2, varscan2
- NF1 | c.-17C>T | 5'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.673T>A | RNA (SNP) | VAF 76/323 reads (24%) | called by muse, mutect2, varscan2
- PLA2G6 | c.609+11G>T | Intron (SNP) | VAF 43/156 reads (28%) | called by muse, mutect2, varscan2
- RNF170 | chr8:42896608 G>A | 5'Flank (SNP) | VAF 5/54 reads (9%) | catalogued as rs1372602192; called by muse, mutect2
- RPSAP52 | n.922G>A | RNA (SNP) | VAF 17/83 reads (20%) | catalogued as rs777650868; called by muse, mutect2, varscan2
- SBNO2 | c.1885+133A>G | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- SCRIB | c.643-25G>T | Intron (SNP) | VAF 17/40 reads (43%) | catalogued as rs950101456, COSV100253489; called by muse, mutect2, varscan2
- TBC1D30 | c.*2671G>T | 3'UTR (SNP) | VAF 61/202 reads (30%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2530T>A | 3'UTR (SNP) | VAF 55/221 reads (25%) | called by muse, mutect2, varscan2
- TOX2 | c.*135G>T | 3'UTR (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
